Somatic mutation profile of tumor specimen TCGA-13-1492-01A (aliquot TCGA-13-1492-01A-01D-0472-01) from TCGA case TCGA-13-1492, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.6 years (24,332 days).
Specimen TCGA-13-1492-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11f5fe2e-bd0b-44cd-9ade-dddfcf4e2cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-1492-10A (Blood Derived Normal), aliquot TCGA-13-1492-10A-01W-0545-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab3b0b3a-2874-42ea-a739-79cbc654519e

The open-access MAF lists 70 somatic variants for this specimen: 49 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 19, Nonsense Mutation 8, Frame Shift Del 4, Intron 1, In Frame Del 1, Frame Shift Ins 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MLH1 | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs63751221, CM990855, COSV51614696; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1458del p.L486Ffs*9 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | catalogued as rs1555286611; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.559+1G>T p.X187_splice | Splice Site (SNP) | VAF 94/104 reads (90%) | hotspot (GDC flag); catalogued as CS137624, COSV52670017, COSV52686439, COSV52695669; called by muse, mutect2, varscan2
- ABCA13 | c.7699C>T p.Q2567* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as rs888924589, COSV71292401; called by muse, mutect2, varscan2
- AKAP3 | c.764G>T p.R255I | Missense Mutation (SNP) | VAF 216/409 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.276); catalogued as COSV57416178, COSV57418116; called by muse, mutect2, varscan2
- ANKEF1 | c.1553T>A p.V518E | Missense Mutation (SNP) | VAF 137/228 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65693093; called by muse, mutect2, varscan2
- CACNA1C | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as rs794727961, COSV59753826; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1C | c.4396C>G p.L1466V | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100217793, COSV59753836; called by muse, mutect2, varscan2
- CUL7 | c.2833A>G p.I945V | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as rs778862752, COSV54820282; called by muse, mutect2, varscan2
- CUX1 | c.1921C>G p.L641V | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as rs1398246789, COSV52909606; called by muse, mutect2, varscan2
- CYP2F1 | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs1401428092, COSV58528460; called by muse, mutect2, varscan2
- DIP2A | c.1961A>G p.Q654R | Missense Mutation (SNP) | VAF 93/208 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV59483613; called by muse, mutect2, varscan2
- F7 | c.1251C>A p.Y417* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV60647299; called by muse, mutect2
- FAM166A | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV100457791, COSV61118377; called by muse, mutect2, varscan2
- FGF23 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 146/419 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs1384170096, COSV52975192; called by muse, mutect2, varscan2
- GLDN | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 114/283 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs371728997; called by muse, mutect2, varscan2
- ICE2 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55033235; called by muse, mutect2, varscan2
- KCNJ9 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866523854; called by muse, mutect2
- KIT | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 284/297 reads (96%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs139694927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAM2 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53061053; called by muse, mutect2
- NEB | c.16045T>G p.Y5349D | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51442910; called by muse, mutect2, varscan2
- NUP155 | c.2284G>T p.E762* (on ENST00000231498 / NM_153485.3; = p.E703* on NM_004298.4) | Nonsense Mutation (SNP) | VAF 137/623 reads (22%) | catalogued as COSV51533016; called by muse, mutect2, varscan2
- NUP188 | c.5113G>A p.G1705R | Missense Mutation (SNP) | VAF 45/192 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65331182; called by muse, mutect2, varscan2
- NUP188 | c.5114G>A p.G1705E | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466824477; called by muse, mutect2, varscan2
- PINK1 | c.1444G>A p.V482M | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as rs773843241, CM1212782, COSV58632262; called by muse, mutect2, varscan2
- PROKR1 | c.834C>A p.C278* | Nonsense Mutation (SNP) | VAF 17/224 reads (8%) | catalogued as rs770223408; called by muse, mutect2
- PRSS35 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.036); catalogued as COSV63801016; called by muse, mutect2, varscan2
- PTEN | c.697del p.R233Dfs*23 | Frame Shift Del (DEL) | VAF 195/284 reads (69%) | catalogued as CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; called by mutect2, pindel, varscan2
- RHOBTB2 | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as rs762216794, COSV52572502; called by muse, mutect2, varscan2
- SH2D2A | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 277/528 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs376035537, COSV100949204, COSV63885095; called by mutect2, varscan2
- SON | c.6622G>A p.D2208N | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.981); catalogued as COSV51671262; called by muse, mutect2
- TFR2 | c.2176G>A p.D726N | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776047688, CM161229, COSV56155673; called by muse, mutect2, varscan2
- TUBAL3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554814613; called by muse, mutect2
- UAP1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs768089603; called by muse, mutect2
- UBR2 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV65751697; called by muse, mutect2, varscan2
- ZNF135 | c.677G>T p.S226I (on ENST00000313434 / NM_001289401.2; = p.S238I on NM_003436.4) | Missense Mutation (SNP) | VAF 381/629 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.094); catalogued as COSV100536352, COSV57882921; called by muse, mutect2, varscan2
- C5orf22 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 12/217 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- DAD1 | c.20_21del p.S7Cfs*89 | Frame Shift Del (DEL) | VAF 43/126 reads (34%) | called by mutect2, pindel, varscan2
- DMP1 | c.100_102del p.K34del | In Frame Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- ECEL1 | c.1325T>G p.L442W | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GOLGA6L9 | c.1267G>T p.E423* | Nonsense Mutation (SNP) | VAF 20/72 reads (28%) | called by muse, mutect2, varscan2
- GP5 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- HOOK3 | c.819A>C p.E273D | Missense Mutation (SNP) | VAF 182/514 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- ITPR3 | c.4020_4021insG p.S1341Vfs*44 | Frame Shift Ins (INS) | VAF 5/53 reads (9%) | called by mutect2, varscan2
- POLD3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- REST | c.763_766del p.Y255Qfs*3 | Frame Shift Del (DEL) | VAF 32/35 reads (91%) | called by mutect2, pindel, varscan2
- TANC2 | c.1685T>C p.L562P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- TRAV1-2 | c.152G>A p.W51* | Nonsense Mutation (SNP) | VAF 18/508 reads (4%) | called by muse, mutect2
- TRIM42 | c.1723T>A p.W575R | Missense Mutation (SNP) | VAF 21/165 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- ERICH3 | c.4314G>A p.E1438= | Silent (SNP) | VAF 58/1532 reads (4%) | called by muse, mutect2
- FAM135B | c.3195C>T p.P1065= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as COSV52732648, COSV52743636; called by muse, mutect2, varscan2
- GDAP1 | c.567G>A p.Q189= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2
- GRM8 | c.657G>A p.S219= | Silent (SNP) | VAF 92/220 reads (42%) | catalogued as rs1319451721, COSV58800882, COSV58802839; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNF1 | c.753G>A p.A251= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as rs1037277372, COSV54464817; called by muse, mutect2, varscan2
- MAP1A | c.5055C>A p.G1685= | Silent (SNP) | VAF 66/126 reads (52%) | catalogued as COSV55809338; called by muse, mutect2, varscan2
- MCHR2 | c.987C>T p.I329= | Silent (SNP) | VAF 30/468 reads (6%) | called by muse, mutect2
- MIEF1 | c.1314C>T p.L438= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV57478099; called by muse, mutect2
- PCDH12 | c.2178G>A p.L726= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2
- PELO | c.310C>T p.L104= | Silent (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- POLD3 | c.255G>A p.L85= | Silent (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- SLC12A4 | c.240G>A p.S80= | Silent (SNP) | VAF 48/51 reads (94%) | catalogued as rs565212919, COSV57933466, COSV57934706; called by muse, mutect2, varscan2
- SRARP | c.24G>A p.R8= | Silent (SNP) | VAF 32/51 reads (63%) | called by muse, mutect2, varscan2
- TEP1 | c.7875T>C p.N2625= | Silent (SNP) | VAF 119/237 reads (50%) | catalogued as rs760883519, COSV52997098; called by muse, mutect2, varscan2
- TNN | c.1707C>T p.D569= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as rs140149976; called by muse, mutect2, varscan2
- TTC14 | c.1932T>C p.Y644= | Silent (SNP) | VAF 80/140 reads (57%) | catalogued as COSV56013434; called by muse, mutect2, varscan2
- TUBGCP6 | c.4305C>T p.Y1435= | Silent (SNP) | VAF 43/44 reads (98%) | catalogued as rs528159783, COSV50567283, COSV99955493; called by muse, mutect2, varscan2
- ZER1 | c.957C>T p.F319= | Silent (SNP) | VAF 29/178 reads (16%) | catalogued as COSV52564812; called by muse, mutect2, varscan2
- ZFYVE26 | c.2451G>A p.L817= | Silent (SNP) | VAF 68/140 reads (49%) | catalogued as COSV61331807; called by muse, mutect2, varscan2
- MIR409 | n.46C>T | RNA (SNP) | VAF 32/75 reads (43%) | catalogued as rs1382576509; called by muse, mutect2, varscan2
- TTN | c.34265-5221G>T | Intron (SNP) | VAF 185/442 reads (42%) | catalogued as COSV100588179; called by muse, mutect2, varscan2
